Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3890, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3890-01A (Primary Tumor).

Diagnosis:

This is a preparation of rectum and sigmoid with an adenocarcinoma of the colon (classification according to topographical aspects) of moderate differentiation and residues of an adenomatous lesion (G2, pT2, L1, V1), also free resection margins and free lymph nodes (pN0, 0 of 12).

Remark:

The anastomosis ring was likewise free of tumor infiltrates.

Source: NCI Genomic Data Commons file 35950312-63ee-4919-a989-78c9a3f68b37 (TCGA-AG-3890.B63BB616-A099-4F40-98DE-E19CE1D3450B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).